Somatic mutation profile of tumor specimen C3L-00156-02 (aliquot CPT0002080008) from CPTAC case C3L-00156, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.2 years (20,525 days).
Specimen C3L-00156-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 622e8fe2-6946-477b-bca9-5acfd1c76f06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00156-31 (Blood Derived Normal), aliquot CPT0004340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8944fd3-9e3d-4150-873d-299b378a0fb8

The open-access MAF lists 2,040 somatic variants for this specimen: 1,402 protein-altering or splice-affecting, 390 silent, 248 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,240, Silent 390, Intron 124, Nonsense Mutation 121, RNA 44, 3'UTR 39, Splice Region 20, 3'Flank 16, 5'UTR 13, Splice Site 12, 5'Flank 12, Frame Shift Ins 5.

Variants (750 of 2,040; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 87/247 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs137852572, CM136027, CM920086, COSV65954067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 135/188 reads (72%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP83 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as rs1207804224, COSV51574274; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.4294C>T p.R1432* | Nonsense Mutation (SNP) | VAF 72/188 reads (38%) | catalogued as rs587779585, CM013250, COSV58591606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP11A1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs121912811, CS021747, COSV51433766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DEPDC5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as rs772872014, CM146220, COSV56694430; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DEPDC5 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 70/188 reads (37%) | catalogued as rs587777459, CM134018, COSV104383263; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSCAM | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs1419539530, COSV68029589; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8326C>T p.R2776* | Nonsense Mutation (SNP) | VAF 55/154 reads (36%) | catalogued as rs137854466, CM940772, COSV57312804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1645A>C p.N549H | Missense Mutation (SNP) | VAF 114/299 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519045, CM020140, COSV60640393, COSV60650624; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- KLHL41 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.66); catalogued as rs730882260, CM1312342, COSV52929638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MVK | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 159/398 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104895301, CM010935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NOBOX | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 61/194 reads (31%) | catalogued as rs193303102, CM118409, COSV56196045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55876538, COSV55894288; called by muse, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 47/167 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>C p.V411L | Missense Mutation (SNP) | VAF 52/126 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57676103, COSV57677068, COSV57683938; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 132/385 reads (34%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 43/148 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.374+2T>G p.X125_splice | Splice Site (SNP) | VAF 52/148 reads (35%) | hotspot (GDC flag); called by muse, mutect2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- ABCA12 | c.1312G>A p.E438K (on ENST00000272895 / NM_173076.3; = p.E120K on NM_015657.3) | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs562998767, COSV55967677; called by muse, varscan2
- ABCB7 | c.628C>T p.R210* (on ENST00000373394 / NM_001271696.3; = p.R211* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 59/170 reads (35%) | catalogued as COSV53724187; called by muse, varscan2
- ABCC10 | c.900C>A p.F300L (on ENST00000372530 / NM_001198934.2; = p.F257L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV55089530; called by muse, mutect2
- ABCC9 | c.2758G>T p.E920* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV99686269; called by muse, mutect2, varscan2
- ABCC9 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV53983907; called by muse, mutect2, varscan2
- ABI1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs749435530, COSV104415219; called by muse, mutect2, varscan2
- ACAA2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs745865904, COSV53270717; called by muse, mutect2, varscan2
- ACACB | c.6097G>T p.E2033* | Nonsense Mutation (SNP) | VAF 51/148 reads (34%) | catalogued as COSV58140308; called by muse, mutect2, varscan2
- ACTA1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as CM095322, COSV64204117; called by muse, mutect2, varscan2
- ACTA2 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as rs1268825216, COSV56515487; called by muse, mutect2, varscan2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, mutect2, varscan2
- ADAMTS1 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs772156527, COSV53173123; called by muse, mutect2, varscan2
- ADAMTS20 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV101240329; called by muse, mutect2, varscan2
- ADCK2 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770769081; called by muse, mutect2, varscan2
- ADCY9 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs372461075; called by muse, varscan2
- ADD2 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs554944629, COSV52459422; called by muse, mutect2, varscan2
- ADGB | c.4537C>T p.Q1513* | Nonsense Mutation (SNP) | VAF 51/156 reads (33%) | catalogued as rs1423214480; called by muse, mutect2
- ADGRB2 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs369924351; called by muse, mutect2
- ADGRB3 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV65414194; called by muse, varscan2
- ADGRF4 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 110/304 reads (36%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.476); catalogued as rs965099809; called by muse, mutect2, varscan2
- ADGRG4 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as COSV54961529; called by muse, mutect2, varscan2
- ADGRL3 | c.3752G>A p.R1251Q (on ENST00000506720 / NM_001322402.2; = p.R1183Q on NM_015236.6) | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189094336, COSV72229226; called by muse, mutect2, varscan2
- AEBP1 | c.2720G>A p.G907D | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470468110, COSV99788486; called by muse, mutect2, varscan2
- AFF1 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.077); catalogued as COSV100320724, COSV57123022; called by muse, mutect2, varscan2
- AFP | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs781592078, COSV56927383; called by muse, mutect2, varscan2
- AHNAK2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.117); catalogued as rs192363522, COSV60924082; called by muse, mutect2, varscan2
- AKAP12 | c.4365G>T p.E1455D | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs943349852, COSV53573607; called by muse, mutect2, varscan2
- AKAP13 | c.7670C>T p.A2557V (on ENST00000394518 / NM_007200.5; = p.A2561V on NM_006738.6) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1236425337; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 83/243 reads (34%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AL645922.1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159425603; called by muse, mutect2, varscan2
- ALG1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 128/370 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757427972; called by muse, mutect2, varscan2
- ALG8 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs140716983; called by muse, mutect2, varscan2
- ALLC | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757104090, COSV52993453; called by muse, mutect2, varscan2
- ALPK1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs377063660, COSV51584702; called by muse, mutect2, varscan2
- ALPP | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.821); catalogued as rs750382140, COSV67397766; called by muse, mutect2
- AMBRA1 | c.2225G>A p.R742H (on ENST00000458649 / NM_001367468.1; = p.R652H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs753438290, COSV54051560; called by muse, mutect2, varscan2
- ANGPTL5 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV57533801; called by muse, mutect2, varscan2
- ANK3 | c.5531C>A p.S1844* | Nonsense Mutation (SNP) | VAF 64/176 reads (36%) | catalogued as COSV55067486; called by muse, mutect2, varscan2
- ANKDD1A | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs758763020, COSV63087657; called by muse, mutect2, varscan2
- ANKRD12 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100041185; called by muse, mutect2, varscan2
- ANKRD22 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs758073859, COSV64236209; called by muse, mutect2, varscan2
- ANKRD30A | c.3022G>T p.E1008* (on ENST00000611781; = p.E952* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as rs1564583067, COSV100654250, COSV64604394; called by muse, mutect2, varscan2
- ANKRD30B | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs1346383926; called by muse, varscan2
- ANKRD33B | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365710850; called by muse, mutect2, varscan2
- ANKRD36B | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99307846; called by muse, mutect2, varscan2
- ANKS1B | c.3547G>A p.E1183K (on ENST00000547776 / NM_152788.4; = p.E349K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372408713; called by muse, mutect2, varscan2
- ANKS1B | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs374815422, COSV61353917; called by muse, mutect2, varscan2
- ANOS1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 141/419 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs199725550, COSV52915809; called by muse, mutect2, varscan2
- AP002495.1 | c.481C>T p.R161C (on ENST00000528511; = p.R92C on NM_001375848.1) | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs139686958; called by muse, mutect2, varscan2
- APC | c.6086C>A p.S2029Y | Missense Mutation (SNP) | VAF 120/300 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99964923, COSV99964952; called by muse, mutect2, varscan2
- APOB | c.11216A>G p.D3739G | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV51923586; called by muse, mutect2, varscan2
- APOBEC3G | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV68470544; called by muse, mutect2, varscan2
- APPL2 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs777772134; called by muse, mutect2, varscan2
- ARHGEF6 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99166555; called by muse, mutect2, varscan2
- ARMCX2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs781812794, COSV57529190; called by muse, mutect2, varscan2
- ART3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.232); catalogued as rs947944389; called by muse, mutect2, varscan2
- ASB15 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV51925718; called by muse, mutect2, varscan2
- ASB2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768806227; called by muse, mutect2, varscan2
- ASB5 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 52/176 reads (30%) | catalogued as rs370097719; called by muse, mutect2, varscan2
- ASH1L | c.7582C>T p.R2528C (on ENST00000368346 / NM_001366177.2; = p.R2523C on NM_018489.3) | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs1376913986, COSV64208707; called by muse, mutect2, varscan2
- ASPM | c.6460T>G p.Y2154D | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.579); catalogued as rs1489746209; called by muse, mutect2, varscan2
- ASXL1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763319023; called by muse, mutect2, varscan2
- ASXL3 | c.2602G>A p.V868I | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs767340081, COSV52473139; called by muse, mutect2, varscan2
- ATF1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs1368652697; called by muse, mutect2, varscan2
- ATF7IP | c.2231C>T p.S744L | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs760359935, COSV53772612; called by muse, mutect2, varscan2
- ATF7IP | c.3562C>T p.R1188* | Nonsense Mutation (SNP) | VAF 95/307 reads (31%) | catalogued as COSV99661506; called by muse, mutect2, varscan2
- ATF7IP | c.3731G>A p.R1244Q | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99661120; called by muse, mutect2, varscan2
- ATP13A5 | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as rs753509516, COSV60877842; called by muse, mutect2
- ATP9B | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as rs754999879; called by mutect2, varscan2
- ATRAID | c.836G>A p.R279Q (on ENST00000611786; = p.R166Q on NM_016085.5) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs148460328, COSV53029566; called by muse, mutect2, varscan2
- AXDND1 | c.2647C>T p.R883* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as rs761897633, COSV62640876, COSV62646075; called by muse, mutect2, varscan2
- B3GAT2 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 69/204 reads (34%) | catalogued as COSV100017095; called by muse, mutect2, varscan2
- B4GALT2 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765252809, COSV52542941; called by muse, mutect2, varscan2
- BCL9 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1553204269, COSV52347096; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4074G>T p.K1358N | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV104418726; called by muse, mutect2, varscan2
- BLK | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 94/288 reads (33%) | catalogued as rs771692863; called by muse, mutect2, varscan2
- BLM | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1279814185, COSV61924196; ClinVar: uncertain significance; called by muse, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BRCA1 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as COSV58802697; called by muse, mutect2, varscan2
- BTAF1 | c.5225G>A p.R1742H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56430044; called by muse, mutect2, varscan2
- BTBD11 | c.3257C>T p.T1086M (on ENST00000280758 / NM_001018072.2; = p.T623M on NM_001017523.2) | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs865847862; called by muse, mutect2, varscan2
- C10orf90 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1386226244, COSV52951341; called by muse, mutect2, varscan2
- C12orf4 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs532268400, COSV54205508; called by muse, mutect2, varscan2
- C19orf57 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as rs778468764; called by muse, mutect2, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2, varscan2
- C6 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99667438, COSV99668001; called by muse, mutect2, varscan2
- C7 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100495523, COSV57474578; called by muse, mutect2, varscan2
- CA8 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs201131573, COSV58771470; called by muse, mutect2, varscan2
- CACNA1A | c.4218C>A p.F1406L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV64192976; called by muse, mutect2, varscan2
- CACNA1E | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373651535, COSV62386777; called by muse, mutect2, varscan2
- CACNG4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.205); catalogued as rs760271953, COSV50924221; called by muse, mutect2, varscan2
- CALCOCO1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759818625; called by muse, varscan2
- CALCR | c.1211C>T p.A404V (on ENST00000649521 / NM_001164737.2; = p.A388V on NM_001742.4) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749628730, COSV100810913, COSV64009509; called by muse, mutect2, varscan2
- CAP2 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772168818, COSV57734886; called by muse, mutect2, varscan2
- CAPZA3 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 78/222 reads (35%) | catalogued as rs15547; called by muse, mutect2, varscan2
- CARMIL3 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs774904740, COSV100549663; called by muse, mutect2, varscan2
- CATSPERB | c.1055A>C p.K352T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV104373727; called by muse, mutect2, varscan2
- CATSPERG | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs147603617; called by muse, mutect2, varscan2
- CBL | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755244263, COSV50633583; called by mutect2, varscan2
- CBR3 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1431131951; called by muse, mutect2, varscan2
- CCBE1 | c.554-5C>A | Splice Region (SNP) | VAF 126/384 reads (33%) | catalogued as rs762279744; called by muse, mutect2, varscan2
- CCDC144A | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs777407520, COSV60697225, COSV60699146; called by muse, mutect2, varscan2
- CCDC168 | c.12316G>A p.A4106T | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.827); catalogued as rs781110117; called by muse, mutect2, varscan2
- CCDC174 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs761797850, COSV57980753; called by muse, varscan2
- CCDC7 | c.4028C>T p.S1343L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); catalogued as rs761341812, COSV56539494; called by muse, mutect2, varscan2
- CCDC81 | c.1903G>A p.E635K (on ENST00000445632 / NM_001156474.2; = p.E545K on NM_021827.4) | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs778361099; called by muse, mutect2, varscan2
- CCNB2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55595993; called by muse, mutect2, varscan2
- CCNT1 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.859); catalogued as rs758820620, COSV56062975; called by muse, mutect2, varscan2
- CCNT2 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV51472643; called by muse, mutect2, varscan2
- CCP110 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757100100; called by muse, mutect2, varscan2
- CCT6B | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs755333614, COSV58487981; called by muse, mutect2, varscan2
- CD163 | c.3302C>A p.S1101Y | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.896); catalogued as rs1250219603, COSV63134475, COSV63137975; called by muse, mutect2, varscan2
- CD300C | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1211142816; called by muse, mutect2, varscan2
- CD47 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs992302821, COSV62527973; called by muse, varscan2
- CD5 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs764750821, COSV61718044; called by muse, mutect2, varscan2
- CD82 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs761257124, COSV57036058; called by muse, mutect2, varscan2
- CDA | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66752043; called by muse, mutect2, varscan2
- CDH26 | c.2261C>T p.P754L (on ENST00000348616 / NM_177980.4; = p.P87L on NM_021810.6) | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs200963310, COSV54849775; called by muse, mutect2, varscan2
- CDK13 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1554335512, COSV51703082, COSV99476032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDON | c.3490G>A p.A1164T | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757589429, COSV54995339; called by muse, mutect2, varscan2
- CELF4 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.156); catalogued as rs765103903, COSV58450078; called by muse, varscan2
- CEP128 | c.2452C>A p.L818I | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.851); catalogued as rs1249994990; called by muse, mutect2, varscan2
- CEP170B | c.1227C>A p.F409L (on ENST00000453495; = p.F338L on NM_015005.3) | Missense Mutation (SNP) | VAF 120/299 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV101371517; called by muse, mutect2, varscan2
- CEP295 | c.3905C>T p.S1302L | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs766963851, COSV57347716; called by muse, mutect2, varscan2
- CEP350 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780482124; called by muse, mutect2, varscan2
- CEP350 | c.6892C>A p.L2298I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62601052; called by muse, mutect2, varscan2
- CEP68 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs764493393, COSV53128934; called by muse, mutect2, varscan2
- CFAP20DC | c.499C>T p.R167W (on ENST00000482387 / NM_001351530.2; = p.R42W on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551035885, COSV55919736; called by muse, mutect2, varscan2
- CFAP221 | c.2135A>G p.D712G | Missense Mutation (SNP) | VAF 88/120 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs917358786; called by muse, mutect2, varscan2
- CFAP251 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs759115110, COSV56608100; called by muse, mutect2, varscan2
- CFAP58 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 43/140 reads (31%) | catalogued as COSV57211244; called by muse, mutect2, varscan2
- CFAP61 | c.1268C>A p.S423Y | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV55634704; called by muse, mutect2, varscan2
- CFAP70 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV60286329; called by muse, mutect2, varscan2
- CHD1 | c.3113G>T p.R1038I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99399230; called by muse, mutect2, varscan2
- CHD7 | c.6158G>A p.R2053Q | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV71110838; called by muse, mutect2, varscan2
- CHMP2A | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 89/279 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs960083867; called by muse, mutect2, varscan2
- CHMP2B | c.425-7C>T | Splice Region (SNP) | VAF 45/152 reads (30%) | catalogued as COSV55461208; called by muse, mutect2, varscan2
- CHPF2 | c.1627C>A p.L543I | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.415); catalogued as COSV50389027; called by muse, mutect2, varscan2
- CHST15 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs375217023; called by muse, mutect2, varscan2
- CIAO3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs753398706, COSV52403764; called by muse, mutect2, varscan2
- CIDEB | c.440T>C p.F147S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773522747; called by muse, mutect2, varscan2
- CLASP2 | c.4372C>T p.R1458W (on ENST00000359576; = p.R1457W on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56279532; called by muse, mutect2, varscan2
- CLDN2 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs138227214; called by muse, mutect2, varscan2
- CLVS2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs750382549, COSV51562393, COSV51567732; called by muse, mutect2, varscan2
- CNGA4 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs748233188; called by muse, mutect2, varscan2
- CNTNAP2 | c.3197A>G p.Y1066C | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100664068, COSV62167993; called by muse, mutect2
- CNTNAP5 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs746996523, COSV70517446; called by muse, mutect2, varscan2
- CNTNAP5 | c.3700C>T p.R1234* | Nonsense Mutation (SNP) | VAF 35/141 reads (25%) | catalogued as rs982218609, COSV70474001, COSV70477179; called by muse, mutect2, varscan2
- COL12A1 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs577784031, COSV100486418; called by muse, mutect2, varscan2
- COL4A3 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs778166354, COSV67414472; called by muse, mutect2, varscan2
- COMMD10 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397108489; called by muse, mutect2, varscan2
- COPB2 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997945949; called by muse, mutect2, varscan2
- CORO6 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs562749110; called by muse, mutect2, varscan2
- CPB1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs745606506, COSV51577199; called by muse, mutect2, varscan2
- CPN1 | c.439T>C p.Y147H | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV64942236; called by muse, mutect2
- CPNE5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 102/118 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777743559, COSV55194807; called by muse, mutect2, varscan2
- CPS1 | c.3336+2T>C p.X1112_splice | Splice Site (SNP) | VAF 44/136 reads (32%) | catalogued as rs1272460783; called by muse, mutect2, varscan2
- CRB2 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1043719019, COSV63502810; called by muse, mutect2, varscan2
- CREM | c.332G>A p.R111H (on ENST00000429130; = p.R62H on NM_001881.3) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs759061714; called by muse, mutect2, varscan2
- CRIM1 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 57/175 reads (33%) | catalogued as rs1365115540, COSV54867948; called by muse, mutect2, varscan2
- CROCC2 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1559595935; called by muse, mutect2, varscan2
- CSF1 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100294601, COSV60032493; called by muse, mutect2, varscan2
- CSF2RA | c.1128C>T p.I376= | Splice Region (SNP) | VAF 70/204 reads (34%) | catalogued as rs1318340896; called by muse, varscan2
- CSMD3 | c.3269C>A p.S1090Y (on ENST00000297405 / NM_001363185.1; = p.S986Y on NM_052900.3) | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV52100273, COSV99838518; called by muse, varscan2
- CTCFL | c.632G>T p.R211I | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs147254483, COSV104389563; called by muse, varscan2
- CTNNA2 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753550582, COSV58139782, COSV58140798; called by muse, mutect2, varscan2
- CTNNB1 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62694859; called by muse, mutect2, varscan2
- CUL4B | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 68/220 reads (31%) | catalogued as CM151182, COSV60689694; called by muse, mutect2, varscan2
- CUL7 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1003166936; called by muse, mutect2, varscan2
- CYB5D2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs551095781; called by muse, mutect2, varscan2
- CYLC2 | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs1181955803; called by muse, mutect2
- CYP11B2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 120/371 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs781165909; called by muse, mutect2, varscan2
- CYP4Z1 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as rs774973940, COSV61964089; called by muse, mutect2, varscan2
- DACH2 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV64183018; called by muse, mutect2, varscan2
- DBF4 | c.380C>A p.S127* | Nonsense Mutation (SNP) | VAF 36/74 reads (49%) | catalogued as COSV55999440; called by muse, mutect2, varscan2
- DCHS1 | c.6403G>A p.E2135K | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166792634, COSV55042640; called by muse, mutect2, varscan2
- DDR2 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 142/401 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV104425681; called by muse, mutect2, varscan2
- DDX21 | c.1382A>C p.K461T | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as rs1391215998; called by muse, mutect2, varscan2
- DDX24 | c.1622A>C p.K541T | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs1287812857; called by muse, mutect2, varscan2
- DDX50 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV65291862; called by muse, mutect2, varscan2
- DDX50 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs375122404; called by muse, mutect2, varscan2
- DGKD | c.2042C>T p.S681L (on ENST00000264057 / NM_152879.3; = p.S637L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs896749700; called by muse, mutect2, varscan2
- DHRS7B | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766967306; called by muse, mutect2, varscan2
- DHRSX | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754962533; called by muse, mutect2, varscan2
- DIDO1 | c.6020C>T p.S2007L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56615601; called by muse, mutect2, varscan2
- DISP1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs760562145, CM166807, COSV52658246; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMXL2 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749262883, COSV51842922; called by muse, mutect2, varscan2
- DNAH10 | c.7871G>A p.R2624Q (on ENST00000409039; = p.R2563Q on NM_207437.3) | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs200270614, COSV68996917; called by muse, mutect2, varscan2
- DNAH2 | c.10459A>G p.T3487A | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1362318248; called by muse, mutect2, varscan2
- DNAH6 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs966457262, COSV52863350; called by muse, mutect2, varscan2
- DNAH6 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV52850534; called by muse, varscan2
- DNAH7 | c.8881C>T p.R2961* | Nonsense Mutation (SNP) | VAF 56/177 reads (32%) | catalogued as rs780242250, COSV56757015; called by muse, mutect2, varscan2
- DNAH8 | c.10117G>T p.E3373* | Nonsense Mutation (SNP) | VAF 64/155 reads (41%) | catalogued as COSV59438136, COSV59443661; called by muse, mutect2, varscan2
- DNAH9 | c.4904A>G p.N1635S | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs748171441; called by muse, mutect2, varscan2
- DNAJC1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1172518642, COSV65410402; called by muse, mutect2, varscan2
- DNAJC13 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754878524, COSV99608195; called by muse, mutect2, varscan2
- DNAJC6 | c.2454G>T p.E818D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.33); catalogued as COSV99674915; called by muse, mutect2, varscan2
- DNASE1L3 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV59156871; called by muse, mutect2, varscan2
- DNASE1L3 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.785); catalogued as rs1363344312; called by muse, mutect2, varscan2
- DNHD1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs375986794; called by muse, mutect2
- DNMBP | c.3455C>T p.S1152L | Missense Mutation (SNP) | VAF 144/334 reads (43%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.472); catalogued as rs368368077; called by muse, mutect2, varscan2
- DNTTIP2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs1246692499, COSV63283876; called by muse, mutect2, varscan2
- DOK5 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99373015; called by muse, mutect2, varscan2
- DOK5 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as rs973360911, COSV99373380; called by muse, mutect2, varscan2
- DSC1 | c.1948G>T p.D650Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242235356, COSV99937104; called by muse, mutect2, varscan2
- DSC1 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 37/160 reads (23%) | catalogued as COSV57147530; called by muse, mutect2, varscan2
- DSCAML1 | c.952C>T p.R318C (on ENST00000321322; = p.R258C on NM_020693.4) | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58384642; called by muse, mutect2, varscan2
- DSPP | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.387); catalogued as rs199906213, COSV56807314, COSV99217455; called by muse, mutect2, varscan2
- DUSP16 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372330415; called by muse, mutect2, varscan2
- DUXA | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs769801044, COSV73729815; called by muse, mutect2, varscan2
- DYNC1H1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs763005275, COSV64135862; called by muse, mutect2, varscan2
- DYNC2H1 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 30/89 reads (34%) | catalogued as COSV62088003; called by muse, mutect2, varscan2
- DYNC2H1 | c.11566G>T p.D3856Y | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs772301450; called by muse, mutect2, varscan2
- DYNLRB1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV55964864; called by muse, mutect2, varscan2
- DZIP1L | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100551554; called by muse, mutect2, varscan2
- EFCAB12 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs542010344, COSV58174782; called by muse, mutect2, varscan2
- EFCAB13 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs149684195; called by muse, mutect2, varscan2
- EIF2B4 | c.1031G>A p.R344Q (on ENST00000347454 / NM_001034116.2; = p.R343Q on NM_015636.3) | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs141025043; called by muse, mutect2, varscan2
- EIF4G2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101151056; called by muse, mutect2, varscan2
- EML5 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs769960454, COSV61352744; called by muse, mutect2, varscan2
- ENOPH1 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 85/229 reads (37%) | catalogued as rs1467637978; called by muse, mutect2, varscan2
- ENPEP | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs546059710, COSV54454005, COSV54454423; called by muse, mutect2, varscan2
- ENPP5 | c.836T>C p.F279S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV100040587; called by muse, mutect2, varscan2
- EPHA1 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV51972727; called by muse, mutect2, varscan2
- EPHB1 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370164002; called by muse, mutect2, varscan2
- ERBB4 | c.2447G>T p.G816V | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61470885; called by muse, mutect2, varscan2
- ETS1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV60093192; called by muse, mutect2, varscan2
- EXD1 | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100153763; called by muse, mutect2, varscan2
- F11 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 96/233 reads (41%) | catalogued as COSV53005022, COSV53008842; called by muse, mutect2, varscan2
- F13A1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 117/313 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs376147795, CM146351; called by muse, mutect2, varscan2
- FAM118B | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs1489557127; called by muse, mutect2, varscan2
- FAM120C | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100070533; called by muse, mutect2, varscan2
- FAM153A | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as rs1231236575, COSV100647113; called by mutect2, varscan2
- FAM184A | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416369528, COSV58858282; called by muse, mutect2, varscan2
- FAM24B | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750572967, COSV59028181; called by muse, mutect2, varscan2
- FAM47A | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.271); catalogued as rs1312961723, COSV60495609; called by muse, mutect2, varscan2
- FAM81A | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 90/251 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs746953331, COSV55676948; called by muse, mutect2, varscan2
- FAM91A1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs778651860, COSV58235836; called by muse, mutect2, varscan2
- FAN1 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs761162643, COSV62951263; called by muse, varscan2
- FANCC | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs369636116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT1 | c.7666C>T p.R2556* | Nonsense Mutation (SNP) | VAF 44/141 reads (31%) | catalogued as rs921535768, COSV71671661; called by muse, mutect2, varscan2
- FAT2 | c.9487G>A p.D3163N | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.588); catalogued as rs141162743; called by muse, mutect2, varscan2
- FBXL20 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs1307073259; called by muse, mutect2, varscan2
- FCGRT | c.326-8C>T | Splice Region (SNP) | VAF 16/47 reads (34%) | catalogued as rs775782740; called by muse, mutect2, varscan2
- FER1L6 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs746744523, COSV67548142; called by muse, mutect2, varscan2
- FERMT1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 114/321 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs914756695; called by muse, mutect2, varscan2
- FES | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs756091713, COSV100182713; called by muse, mutect2, varscan2
- FGA | c.2482G>T p.D828Y | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236847957; called by muse, mutect2, varscan2
- FIGNL1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63553302; called by muse, mutect2, varscan2
- FKBP15 | c.3577G>A p.E1193K | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs765429463, COSV99406922; called by muse, mutect2, varscan2
- FKBP15 | c.2120A>C p.K707T | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs932646514; called by muse, mutect2, varscan2
- FKBP6 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.918); catalogued as rs377226318; called by muse, varscan2
- FLACC1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs142904738; called by muse, varscan2
- FLT3 | c.1943-1G>A p.X648_splice | Splice Site (SNP) | VAF 37/107 reads (35%) | catalogued as COSV54067540; called by muse, mutect2, varscan2
- FMNL2 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs770034141, COSV56490865; called by muse, mutect2, varscan2
- FOXD4 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 242/603 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV58701267; called by muse, mutect2, varscan2
- FOXJ2 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs753515605; called by muse, mutect2, varscan2
- FOXP2 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs748878832; called by muse, mutect2, varscan2
- FRMD1 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1387691073; called by muse, mutect2, varscan2
- FRMD6 | c.1555C>T p.R519C (on ENST00000344768 / NM_001267046.2; = p.R511C on NM_152330.4) | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs756601021, COSV100656273; called by muse, mutect2, varscan2
- FRY | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV66566624; called by muse, mutect2, varscan2
- FSIP2 | c.6152G>A p.R2051H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs989704997; called by muse, mutect2, varscan2
- FSIP2 | c.15512G>A p.R5171Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs1433751448; called by muse, mutect2, varscan2
- FZD8 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101020208; called by muse, mutect2, varscan2
- GALNT12 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs748104709, COSV100899135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT14 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs771870260, COSV61103558; called by muse, mutect2
- GALNT3 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.401); catalogued as COSV101204876; called by muse, mutect2, varscan2
- GALNT8 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs200878740, COSV52894184, COSV99362470; called by muse, mutect2, varscan2
- GAP43 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs11557765, COSV100526061; called by muse, mutect2, varscan2
- GAS7 | c.1345C>T p.R449* (on ENST00000432992 / NM_201433.2; = p.R309* on NM_003644.3) | Nonsense Mutation (SNP) | VAF 55/180 reads (31%) | catalogued as rs779994808, COSV60432176; called by muse, mutect2, varscan2
- GAS7 | c.1144G>A p.D382N (on ENST00000432992 / NM_201433.2; = p.D242N on NM_003644.3) | Missense Mutation (SNP) | VAF 116/337 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV60437874; called by muse, mutect2, varscan2
- GCSAML | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs768814265, COSV63577072; called by muse, mutect2, varscan2
- GIPC2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1326682175, COSV66127457; called by muse, mutect2, varscan2
- GIPC3 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 87/333 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs772741956, COSV59259909; called by muse, mutect2, varscan2
- GJA10 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65355988, COSV65356146; called by muse, mutect2, varscan2
- GJA5 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1553227043, COSV54785350; called by muse, mutect2, varscan2
- GJA9 | c.1472T>C p.V491A | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372769729, COSV100668084; called by muse, mutect2, varscan2
- GJA9 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 63/178 reads (35%) | catalogued as COSV62532337; called by muse, mutect2, varscan2
- GJC1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs749762217, COSV57910461; called by muse, mutect2, varscan2
- GKN1 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV65006496; called by muse, mutect2, varscan2
- GLI3 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as rs919463456; called by muse, mutect2, varscan2
- GNAT2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs983915440, COSV63554832, COSV63555145; called by muse, mutect2, varscan2
- GNB2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs1334436346; called by muse, mutect2, varscan2
- GOLGA1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs779800593, COSV65228917, COSV65230774; called by muse, mutect2, varscan2
- GPR158 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391900493, COSV66266132; called by muse, mutect2, varscan2
- GPR174 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 71/198 reads (36%) | catalogued as COSV52134015, COSV99338131; called by muse, mutect2, varscan2
- GPR85 | c.1007C>A p.P336H | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784364; called by muse, mutect2, varscan2
- GPR85 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV99775080; called by muse, mutect2, varscan2
- GRIK3 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV66135379; called by muse, mutect2, varscan2
- GRIN2B | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 90/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74205714; called by muse, mutect2, varscan2
- GRM7 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs1025403472, COSV100735833, COSV63173475, COSV99066173; called by muse, mutect2, varscan2
- GRM8 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760631675, COSV58874971; called by muse, mutect2, varscan2
- GRM8 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.734); catalogued as rs758371200, COSV58804439; called by muse, mutect2
- GRTP1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200353233, COSV100208658, COSV58151791; called by muse, mutect2, varscan2
- GTF3C1 | c.3655C>T p.R1219W | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs184708220, COSV62239545; called by muse, mutect2, varscan2
- H1-7 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 104/312 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1212008905, COSV58601927; called by muse, mutect2
- HADH | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 133/404 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs1292646768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAUS7 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV57848038, COSV57848209, COSV57851414; called by muse, mutect2, varscan2
- HCN1 | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as CM145439, COSV57508227; called by muse, mutect2, varscan2
- HECTD3 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV55799050; called by muse, mutect2, varscan2
- HECW1 | c.4663C>T p.R1555W | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs754041766, COSV67823226; called by muse, mutect2, varscan2
- HEPACAM | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs542132168, COSV53428520; called by muse, mutect2, varscan2
- HERC2 | c.11716C>T p.R3906C | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs770688775, COSV55314887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHIP | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV56836355, COSV56839702, COSV56843149; called by muse, mutect2, varscan2
- HMBOX1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55070218; called by muse, mutect2, varscan2
- HMCN2 | c.10850C>T p.S3617L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.609); catalogued as rs1157190650; called by muse, mutect2, varscan2
- HNF4A | c.827T>C p.F276S | Missense Mutation (SNP) | VAF 131/379 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs748284293; called by muse, mutect2, varscan2
- HSD17B4 | c.2102A>G p.Y701C (on ENST00000414835 / NM_001199291.3; = p.Y676C on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs764128703; called by muse, mutect2, varscan2
- HTR1A | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1479266939; called by muse, mutect2, varscan2
- HTR2B | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs763569593, COSV51449510; called by muse, mutect2
- HTT | c.5718C>T p.V1906= | Splice Region (SNP) | VAF 28/69 reads (41%) | catalogued as rs759556699; called by muse, mutect2
- HTT | c.6596C>T p.A2199V | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs750741890; called by muse, varscan2
- HYDIN | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751217729; called by mutect2, varscan2
- IFIH1 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 131/402 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs747135877, COSV55125526; called by muse, mutect2, varscan2
- IFNA10 | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.047); catalogued as rs1295595696; called by muse, mutect2, varscan2
- IFT122 | c.2393G>A p.R798H (on ENST00000348417 / NM_052989.3; = p.R739H on NM_018262.4) | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs755677495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFT140 | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055889482; called by muse, mutect2, varscan2
- IGF1R | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1361565953, COSV51292187; called by muse, mutect2, varscan2
- IGF2R | c.3283G>A p.D1095N | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776131275, COSV63632634; called by muse, mutect2, varscan2
- IGSF1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs369648621; called by muse, mutect2, varscan2
- IGSF10 | c.2788G>T p.D930Y | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99177115; called by muse, mutect2, varscan2
- IL1B | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772717932; called by muse, mutect2, varscan2
- IL22RA1 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs772297728; called by muse, mutect2, varscan2
- INAVA | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs147797258, COSV66256482; called by muse, mutect2, varscan2
- INTS6L | c.2393G>T p.R798I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1556534187; called by muse, mutect2, varscan2
- IPP | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV63431983; called by muse, mutect2
- IQSEC3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.494); catalogued as rs1349450318; called by muse, mutect2, varscan2
- IRAK1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782663308, COSV57653376; called by muse, mutect2, varscan2
- IRAK3 | c.373T>G p.L125V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs755086629; called by muse, mutect2, varscan2
- ITGA9 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs759937611, COSV53242831; called by muse, mutect2, varscan2
- ITPR2 | c.2726A>C p.K909T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs1249502113; called by muse, mutect2, varscan2
- IVL | c.447A>C p.K149N | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.187); catalogued as COSV100908307, COSV64215682; called by muse, mutect2, varscan2
- IZUMO1R | c.409C>T p.R137C (on ENST00000440961; = p.R144C on NM_001199206.3) | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs776768539, COSV60623553; called by muse, mutect2, varscan2
- IZUMO2 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53230244, COSV53231213; called by muse, mutect2, varscan2
- JAK2 | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs1346944271, CM141662, COSV67602992; called by muse, mutect2, varscan2
- JPH2 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1244082467; called by muse, mutect2, varscan2
- JPH3 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 111/308 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767533433, COSV52465531; called by muse, mutect2, varscan2
- KANK1 | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs771153243; called by muse, mutect2, varscan2
- KAT6A | c.4708G>A p.D1570N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55906756; called by muse, mutect2, varscan2
- KATNBL1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.689); catalogued as rs369374470, COSV56622598; called by muse, mutect2, varscan2
- KCNA5 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375520270, COSV52904004; called by muse, mutect2, varscan2
- KCNB2 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 92/237 reads (39%) | catalogued as rs1359414670; called by muse, mutect2, varscan2
- KCNB2 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs557129070, COSV73052458; called by muse, mutect2, varscan2
- KCND2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); catalogued as COSV58579127; called by muse, mutect2, varscan2
- KCNJ16 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs200507298; called by muse, mutect2, varscan2
- KCNK2 | c.745G>A p.E249K (on ENST00000444842 / NM_001017425.3; = p.E234K on NM_014217.4) | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67202886; called by muse, mutect2, varscan2
- KCNV1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.134); catalogued as COSV52084940; called by muse, mutect2, varscan2
- KIAA0825 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs754046124; called by muse, mutect2, varscan2
- KIAA1109 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1238937431, COSV52684384; called by muse, mutect2, varscan2
- KIAA1217 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1351845734, COSV56815823; called by muse, mutect2, varscan2
- KIF14 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs373895990, COSV66259940; called by muse, mutect2, varscan2
- KIF20B | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs770111248; called by muse, mutect2, varscan2
- KIF21A | c.2314C>T p.R772C (on ENST00000361418 / NM_001378440.1; = p.R759C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs778271459, COSV62768010; called by muse, mutect2, varscan2
- KLC4 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1304846100, COSV99431637; called by muse, mutect2, varscan2
- KLHL5 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767326522, COSV54671389, COSV54672017; called by muse, mutect2, varscan2
- KLK7 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as rs780230799, COSV100304410; called by muse, varscan2
- KMT2C | c.2501A>C p.K834T | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51500931; called by muse, varscan2
- LAMA1 | c.7748C>T p.A2583V | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs141247075, COSV67542121; called by muse, mutect2, varscan2
- LAMA5 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs139764752; called by muse, mutect2, varscan2
- LENG8 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs765505344, COSV58729344; called by muse, mutect2, varscan2
- LGI2 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.749); catalogued as rs149289586; called by muse, mutect2, varscan2
- LGSN | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs748439660, COSV65726386; called by muse, mutect2, varscan2
- LHFPL3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV67815734; called by muse, varscan2
- LIFR | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs553912841; called by muse, mutect2, varscan2
- LIN9 | c.659C>A p.S220Y (on ENST00000366808 / NM_001270410.2; = p.S165Y on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.819); catalogued as COSV100067896; called by muse, mutect2, varscan2
- LIPC | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 97/284 reads (34%) | catalogued as rs369262181; called by muse, mutect2, varscan2
- LIPH | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 107/281 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV56184370; called by muse, mutect2, varscan2
- LOXHD1 | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 176/521 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs886053832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPAR1 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.207); catalogued as rs527765818; called by muse, mutect2, varscan2
- LPL | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs767509076; called by muse, mutect2, varscan2
- LRBA | c.5626G>A p.E1876K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs760470465, COSV63950351; called by muse, mutect2, varscan2
- LRIF1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 44/135 reads (33%) | catalogued as rs375319628; called by muse, mutect2, varscan2
- LRP2 | c.7165T>G p.F2389V | Missense Mutation (SNP) | VAF 91/252 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV104378299; called by muse, mutect2, varscan2
- LRRC25 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 107/274 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs541540034, COSV59114793; called by muse, mutect2, varscan2
- LRRC75B | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs202133451; called by muse, mutect2, varscan2
- LSP1 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as rs1410605938; called by muse, mutect2, varscan2
- LTA4H | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV68885575; called by muse, mutect2, varscan2
- LYPLA2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV55754771; called by muse, mutect2, varscan2
- M1AP | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1056551335, COSV51847617; called by muse, mutect2, varscan2
- MAGI2 | c.2296C>T p.R766* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as COSV62641404; called by muse, mutect2, varscan2
- MANBA | c.1636C>T p.R546C (on ENST00000642252; = p.R500C on NM_005908.4) | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs763576266, COSV56968724; called by muse, mutect2, varscan2
- MAOA | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 111/333 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as rs1268810174; called by muse, mutect2, varscan2
- MAOA | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs140295792, COSV58641530; called by muse, varscan2
- MAP2 | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 66/201 reads (33%) | catalogued as COSV52283123; called by muse, mutect2, varscan2
- MAP3K13 | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 58/163 reads (36%) | catalogued as COSV53986564, COSV53997598; called by muse, mutect2, varscan2
- MAP3K21 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1186816823, COSV64044859; called by muse, mutect2, varscan2
- MCF2L2 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781000309; called by muse, mutect2, varscan2
- MCMBP | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs142836542; called by mutect2, varscan2
- MCOLN1 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 121/366 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1273086675; called by muse, mutect2, varscan2
- MDGA1 | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866926229; called by muse, mutect2, varscan2
- ME2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs749768516; called by muse, mutect2, varscan2
- MED13 | c.3838C>T p.R1280* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as COSV67262574; called by muse, mutect2, varscan2
- MED13L | c.4766C>T p.S1589L | Missense Mutation (SNP) | VAF 121/311 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs758612829, COSV56117486; called by muse, mutect2, varscan2
- MED17 | c.860-7C>T | Splice Region (SNP) | VAF 43/128 reads (34%) | catalogued as COSV99316022; called by muse, mutect2, varscan2
- METTL6 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs775423616; called by muse, mutect2, varscan2
- MEX3B | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV61663356; called by muse, mutect2, varscan2
- MFSD6 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758758860, COSV55621956; called by muse, mutect2, varscan2
- MFSD6L | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs149431404; called by muse, mutect2, varscan2
- MGA | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54958918, COSV54960833; called by muse, mutect2, varscan2
- MIA2 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs762661827, COSV54482489; called by muse, mutect2, varscan2
- MIOS | c.2534A>G p.D845G | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60768741; called by muse, mutect2, varscan2
- MMGT1 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV100018527; called by muse, mutect2, varscan2
- MORF4L2 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as rs200858326, COSV64610684, COSV64610951; called by muse, mutect2, varscan2
- MORN4 | c.167T>G p.F56C | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs974195977; called by muse, varscan2
- MOSPD2 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs956150373; called by muse, mutect2, varscan2
- MPP6 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV99757559; called by muse, mutect2, varscan2
- MRPL18 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 83/266 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs201216825; called by muse, mutect2, varscan2
- MRPL39 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs969278422, COSV56261506; called by muse, mutect2, varscan2
- MS4A4E | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV101301579; called by muse, mutect2, varscan2
- MS4A5 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100281014; called by muse, mutect2, varscan2
- MSH4 | c.1251G>T p.K417N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs1352193700, COSV54200605; called by muse, mutect2, varscan2
- MUC16 | c.6292A>G p.T2098A | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs1473125234; called by muse, mutect2, varscan2
- MUC19 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs1352982047; called by muse, mutect2, varscan2
- MXRA5 | c.4481C>T p.S1494L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764545839, COSV54232960; called by muse, mutect2, varscan2
- MYBPC2 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs756106442, COSV100732059; called by muse, mutect2, varscan2
- MYCBP2 | c.1858G>A p.E620K (on ENST00000357337; = p.E658K on NM_015057.5) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV104419495; called by muse, varscan2
- MYH3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 115/359 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs1396728749, COSV56870002; called by muse, mutect2, varscan2
- MYOM1 | c.4711C>T p.R1571C | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373419422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAALAD2 | c.1550G>A p.R517K | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV58959701; called by muse, mutect2
- NACA2 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 114/334 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.198); catalogued as rs765292291; called by muse, mutect2, varscan2
- NALCN | c.2525G>T p.R842L | Missense Mutation (SNP) | VAF 96/313 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51943813; called by muse, mutect2, varscan2
- NDRG1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 112/319 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1337832950, COSV60482717, COSV60482725; called by muse, mutect2, varscan2
- NEK11 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1560563226; called by muse, mutect2, varscan2
- NEO1 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368178634; called by muse, mutect2, varscan2
- NEO1 | c.3910C>T p.R1304* | Nonsense Mutation (SNP) | VAF 47/146 reads (32%) | catalogued as rs1194933780, COSV56067714; called by muse, mutect2, varscan2
- NFASC | c.2279A>G p.N760S (on ENST00000339876 / NM_001378329.1; = p.N756S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1239075535; called by muse, mutect2, varscan2
- NFATC2 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760805900; called by muse, mutect2, varscan2
- NFATC4 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs148765202; called by muse, mutect2, varscan2
- NFE2L3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs770073786, COSV50231327; called by muse, mutect2, varscan2
- NIPBL | c.5441G>A p.R1814Q | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs1233390832; called by muse, varscan2
- NLGN1 | c.1686C>A p.F562L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as rs1346882966, COSV100849559, COSV64344450; called by muse, varscan2
- NLRC4 | c.2087G>A p.R696K | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs1213192023; called by muse, mutect2, varscan2
- NLRP11 | c.2598G>T p.E866D | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs779546188; called by muse, mutect2, varscan2
- NLRP11 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.261); catalogued as rs765853030, COSV100789794; called by muse, varscan2
- NLRP13 | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs779259380; called by muse, mutect2, varscan2
- NLRP7 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs866746156, COSV100053357; called by muse, mutect2, varscan2
- NMI | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); catalogued as rs780315335; called by muse, varscan2
- NMT2 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as COSV65381813; called by muse, mutect2, varscan2
- NNMT | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs750805211, COSV55473279, COSV55473688; called by muse, mutect2, varscan2
- NOC3L | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs768698240, COSV64930528; called by muse, mutect2, varscan2
- NOD2 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 142/389 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs200035357; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- NOL4 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52343685; called by muse, mutect2, varscan2
- NOL4 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs762351615, COSV52346303, COSV52353561; called by muse, mutect2, varscan2
- NOP16 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs200749495; called by muse, mutect2, varscan2
- NOTUM | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.204); catalogued as rs1351440465; called by muse, mutect2, varscan2
- NPAP1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs1170974294, COSV61505991; called by muse, mutect2, varscan2
- NPAP1 | c.2738C>A p.S913Y | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV61504085, COSV61507434, COSV61509490; called by muse, mutect2, varscan2
- NPAS4 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as rs1165666142; called by muse, mutect2, varscan2
- NPAS4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs749039442, COSV100215172; called by muse, mutect2, varscan2
- NR1I3 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs745909079, COSV63469095; called by muse, mutect2, varscan2
- NRDE2 | c.1554C>A p.F518L | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV100583721; called by muse, mutect2, varscan2
- NRN1 | c.30T>G p.I10M | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as rs375672175; called by muse, mutect2, varscan2
- NTS | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55456050, COSV99755095; called by muse, mutect2, varscan2
- NUP133 | c.2779A>C p.N927H | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs764079404, COSV99772891; called by muse, mutect2, varscan2
- NUP210L | c.3151C>T p.R1051* | Nonsense Mutation (SNP) | VAF 42/124 reads (34%) | catalogued as rs754015372, COSV55141313, COSV55150896; called by muse, mutect2, varscan2
- NUP37 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs1287673489; called by muse, mutect2, varscan2
- NUTM2D | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs758230831, COSV101096926; called by muse, mutect2, varscan2
- NXF3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs764300277, COSV67702597; called by muse, mutect2, varscan2
- OBSCN | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs781382858; called by muse, mutect2
- OBSCN | c.10936C>T p.R3646W | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs372696460; called by muse, mutect2, varscan2
- OBSL1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750202870; called by muse, mutect2, varscan2
- OMD | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486048291; called by muse, mutect2, varscan2
- OR14K1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs542750150, COSV51722485; called by muse, mutect2, varscan2
- OR2M3 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159595046, COSV71759024; called by muse, mutect2, varscan2
- OR4D10 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV73259986; called by muse, mutect2
- OR4K2 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53850647; called by muse, varscan2
- OR51G2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs760144153, COSV100432256, COSV58992710; called by muse, mutect2, varscan2
- OR56A5 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs776028165, COSV60827354; called by muse, mutect2, varscan2
- OR5AN1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1056756621, COSV58321865, COSV58322176; called by muse, mutect2, varscan2
- OR5D14 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs763435028, COSV104409164, COSV59455793; called by muse, mutect2, varscan2
- OR5K4 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs902873759, COSV61583677; called by muse, mutect2, varscan2
- OR6N2 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59412231; called by muse, mutect2, varscan2
- OR7A17 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as rs755042030; called by muse, mutect2, varscan2
- OR8H1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1369006802, COSV57293417; called by muse, mutect2
- OTOA | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53766416; called by muse, mutect2, varscan2
- OTUD7A | c.2738A>G p.Y913C (on ENST00000307050 / NM_001382637.1; = p.Y906C on NM_130901.3) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as rs1344590142; called by muse, mutect2, varscan2
- OXSM | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs763843023, COSV55002990, COSV99771931; called by muse, mutect2, varscan2
- PABPC4L | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs868469335, COSV69928983; called by muse, mutect2, varscan2
- PADI3 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs139813503; called by muse, mutect2, varscan2
- PAPSS2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780333884, COSV63264331; called by muse, mutect2, varscan2
- PAQR9 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503797; called by muse, mutect2, varscan2
- PARD3B | c.3466C>T p.R1156* (on ENST00000406610 / NM_001302769.2; = p.R1087* on NM_057177.7) | Nonsense Mutation (SNP) | VAF 64/178 reads (36%) | catalogued as rs776213727, COSV100594116; called by muse, mutect2, varscan2
- PARP11 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 49/123 reads (40%) | catalogued as rs142910026; called by muse, mutect2, varscan2
- PASD1 | c.1937A>G p.Q646R | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs1298957137; called by muse, varscan2
- PAX6 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as CM981466; called by muse, mutect2, varscan2
- PCDH15 | c.5632G>A p.E1878K | Missense Mutation (SNP) | VAF 114/332 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV57332938, COSV57416693; called by muse, mutect2, varscan2
- PCDH18 | c.2977G>A p.D993N | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs754884852, COSV61269913; called by muse, mutect2, varscan2
- PCDHA5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 104/295 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65354658; called by muse, mutect2, varscan2
- PCDHA6 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.658); catalogued as COSV67045091; called by muse, varscan2
- PCDHA6 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 110/332 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); catalogued as COSV67040130; called by muse, varscan2
- PCDHB7 | c.2237G>A p.S746N | Missense Mutation (SNP) | VAF 59/569 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); catalogued as COSV99177411; called by muse, mutect2, varscan2
- PCDHGA6 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 206/299 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs567912144, COSV53903141; called by muse, mutect2, varscan2
- PCDHGB4 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544789937, COSV53910620; called by muse, varscan2
- PCDHGB4 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 143/354 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs1201903320, COSV53917768; called by muse, varscan2
- PCLO | c.15101G>T p.R5034I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61623444, COSV61624124; called by muse, mutect2
- PCLO | c.13245C>A p.D4415E | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.361); catalogued as COSV61656107; called by muse, mutect2, varscan2
- PCLO | c.9847C>G p.Q3283E | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100432125; called by muse, mutect2, varscan2
- PDE1C | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58518331; called by muse, mutect2, varscan2
- PDE2A | c.2398C>A p.L800I | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as rs558541576; called by muse, mutect2, varscan2
- PDE3B | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99963177; called by muse, mutect2, varscan2
- PDE8B | c.1712+1G>A p.X571_splice | Splice Site (SNP) | VAF 89/250 reads (36%) | catalogued as rs769945903; called by muse, mutect2, varscan2
- PDSS2 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 117/323 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782099223; called by muse, mutect2, varscan2
- PDZD2 | c.6860C>T p.S2287L | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs748017374, COSV56869179; called by muse, mutect2, varscan2
- PEG3 | c.2431G>A p.D811N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs779401135, COSV55626223, COSV55635648; called by mutect2, varscan2
- PELP1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757839852; called by muse, mutect2, varscan2
- PGLS | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs375302944; called by muse, mutect2, varscan2
- PGS1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs779345585; called by muse, mutect2, varscan2
- PHKB | c.708G>A p.S236= | Splice Region (SNP) | VAF 61/182 reads (34%) | catalogued as rs768892939, COSV54516537, COSV54533171; called by muse, mutect2, varscan2
- PIK3C2A | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.13); catalogued as rs766658261, COSV56402471; called by muse, mutect2, varscan2
- PIWIL1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751181793, COSV55344004; called by muse, mutect2, varscan2
- PJA1 | c.952G>A p.E318K (on ENST00000361478 / NM_145119.4; = p.E130K on NM_022368.5) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs755567716, COSV64053823; called by muse, mutect2, varscan2
- PKD1L1 | c.4061C>A p.S1354Y | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs768164147; called by muse, mutect2, varscan2
- PKD1L3 | c.3956C>T p.S1319L | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs775716960; called by muse, mutect2, varscan2
- PKDREJ | c.5795C>T p.S1932L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759280393, COSV53548704, COSV99478552; called by muse, mutect2, varscan2
- PKP3 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs373102599, COSV58987890; called by muse, mutect2, varscan2
- PLA2G4D | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV51820000; called by muse, mutect2, varscan2
- PLCH2 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs747707446, COSV53943475; called by muse, mutect2, varscan2
- PLCL1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1180602625; called by muse, mutect2, varscan2
- PLEKHD1 | c.858C>A p.S286R | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV59447058; called by muse, mutect2, varscan2
- PLEKHH2 | c.2524C>T p.R842W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773823497, COSV56753746; called by muse, mutect2
- PLEKHM2 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.152); catalogued as rs1304959070; called by muse, mutect2, varscan2
- PLS1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as COSV100538102, COSV61832682; called by muse, mutect2, varscan2
- PMEL | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs201446120, COSV59385171; called by muse, mutect2, varscan2
- POLA1 | c.4067G>A p.R1356Q | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV66884999; called by muse, mutect2, varscan2
- POLQ | c.2425G>A p.V809I | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs764579690; called by muse, mutect2, varscan2
- POLR1A | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs570647558; called by muse, mutect2, varscan2
- POM121L12 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs775755313, COSV68694032; called by muse, mutect2, varscan2
- PPIAL4G | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 93/437 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs1465167332, COSV101343997; called by muse, mutect2, varscan2
- PPP2R2A | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV60096644; called by muse, mutect2, varscan2
- PPP5C | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99181239, COSV99183815; called by muse, mutect2, varscan2
- PQBP1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 126/389 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs959075496; called by muse, mutect2, varscan2
- PRDM11 | c.1348C>T p.R450C (on ENST00000530656 / NM_001359633.1; = p.R416C on NM_001256695.1) | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs753240285, COSV55437400; called by muse, mutect2, varscan2
- PRDM9 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 110/311 reads (35%) | catalogued as rs759447836, COSV57007053, COSV57007170; called by muse, mutect2, varscan2
- PRG4 | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs367728160; called by muse, mutect2, varscan2
- PRKCI | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99041682; called by muse, mutect2, varscan2
- PROM1 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 58/163 reads (36%) | catalogued as rs794726926; called by muse, mutect2, varscan2
- PRR14L | c.4532C>T p.A1511V | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs776813532, COSV100392837; called by muse, mutect2, varscan2
- PRRT4 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV71054148; called by muse, mutect2, varscan2
- PSAPL1 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV59843940; called by muse, mutect2, varscan2
- PSG6 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 42/114 reads (37%) | catalogued as COSV51835600; called by muse, mutect2, varscan2
- PSMA3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs1009646696, COSV53616249; called by muse, mutect2, varscan2
- PTK6 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs374160715; called by muse, mutect2, varscan2
- PTPDC1 | c.805C>T p.R269C (on ENST00000375360 / NM_177995.3; = p.R321C on NM_152422.4) | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376544074; called by muse, mutect2, varscan2
- PTPN13 | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57401541; called by muse, mutect2, varscan2
- PTPN14 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1178678823, COSV65283300; called by muse, mutect2, varscan2
- PTPRD | c.5020C>T p.R1674C | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61931642; called by muse, mutect2, varscan2
- PTPRD | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61927786; called by muse, mutect2, varscan2
- PTPRD | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs1353675904, COSV61936904; called by muse, mutect2, varscan2
- PTPRG | c.3934C>T p.R1312W | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754335459, COSV55661669; called by muse, mutect2, varscan2
- PXDNL | c.4233A>C p.K1411N | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as COSV62500662; called by muse, mutect2, varscan2
- QRSL1 | c.1132C>A p.L378I | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs918445566, COSV64687462; called by muse, mutect2, varscan2
- RABL2A | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 48/209 reads (23%) | catalogued as rs759040194, COSV100905662; called by muse, mutect2, varscan2
- RABL3 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs370379749, COSV56337805; called by muse, mutect2, varscan2
- RAET1G | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs377738718; called by muse, mutect2, varscan2
- RAI2 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100518240; called by muse, mutect2, varscan2
- RALGAPB | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs6100055; called by muse, mutect2, varscan2
- RAPGEF6 | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.262); catalogued as rs761250497, COSV57239227; called by muse, mutect2, varscan2
- RAPGEF6 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 54/146 reads (37%) | catalogued as COSV57244234; called by muse, mutect2, varscan2
- RBAK | c.539T>G p.F180C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs535208058; called by muse, mutect2, varscan2
- RBAK | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1456489524, COSV62330894; called by muse, mutect2, varscan2
- RBM26 | c.327+6G>A | Splice Region (SNP) | VAF 31/62 reads (50%) | catalogued as rs994428448; called by muse, mutect2, varscan2
- RBM39 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53615214, COSV53616264, COSV99488189; called by muse, mutect2, varscan2
- RBMX | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1405359635; called by muse, mutect2, varscan2
- RBMXL3 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.363); catalogued as rs782734644; called by muse, mutect2, varscan2
- RDX | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs759389484, COSV58192676; called by muse, mutect2, varscan2
- REV3L | c.3581G>A p.R1194Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.111); catalogued as rs775715264, COSV62623502; called by muse, mutect2, varscan2
- RFPL2 | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99964504; called by muse, mutect2, varscan2
- RGPD1 | c.1337G>A p.R446Q (on ENST00000409776; = p.R454Q on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.292); catalogued as rs1238009086, COSV101233593; called by mutect2, varscan2
- RGPD4 | c.1775C>A p.S592Y | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61750301; called by muse, mutect2, varscan2
- RGS22 | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs368573670; called by mutect2, varscan2
- RGS22 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1024418694, COSV62660099; called by muse, mutect2, varscan2
- RGSL1 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs896098429, COSV54257292; called by muse, mutect2
- RHOBTB3 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV101183212; called by muse, mutect2, varscan2
- RIC8B | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs771135146; called by muse, mutect2, varscan2
- RIMS2 | c.785C>T p.S262L (on ENST00000666250 / NM_001348490.2; = p.S70L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs1379846193, COSV51661298; called by muse, mutect2, varscan2
- RIPK1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776186590; called by muse, mutect2, varscan2
- RLN1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); catalogued as rs376479792; called by muse, mutect2
- RNF41 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1457922262; called by muse, mutect2, varscan2
- RNF6 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs751113959; called by muse, mutect2, varscan2
- RNF6 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV60417786; called by muse, mutect2, varscan2
- RNMT | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs779338611, COSV51084374; called by muse, mutect2, varscan2
- ROS1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs140178288; called by muse, mutect2, varscan2
- RP1 | c.4666G>T p.E1556* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV55114211; called by muse, mutect2, varscan2
- RPS2 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs1415317836; called by muse, mutect2, varscan2
- RSPH10B2 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs755543190; called by mutect2, varscan2
- RTN4 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 85/252 reads (34%) | catalogued as COSV58267394; called by muse, mutect2, varscan2
- RUNX1T1 | c.712G>A p.E238K (on ENST00000265814 / NM_001198628.1; = p.E211K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs746997350, COSV56139578; called by muse, mutect2
- RXFP2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs201792081; called by muse, mutect2, varscan2
- RYR3 | c.6304C>T p.R2102* | Nonsense Mutation (SNP) | VAF 54/172 reads (31%) | catalogued as COSV101215034, COSV66779787; called by muse, mutect2, varscan2
- RYR3 | c.11881C>A p.L3961I (on ENST00000389232; = p.L3962I on NM_001036.6) | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as COSV66785507; called by muse, mutect2, varscan2
- RYR3 | c.13264G>A p.A4422T (on ENST00000389232; = p.A4423T on NM_001036.6) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs769318881, COSV101212653; called by muse, mutect2, varscan2
- S100A4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs368160023; called by muse, mutect2, varscan2
- SACS | c.7150G>A p.E2384K | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs762896797, COSV66543934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD11 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs765161807; called by muse, mutect2, varscan2
- SAMD15 | c.993G>T p.E331D | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV53627944, COSV53628259; called by muse, mutect2, varscan2
- SAMD3 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs371432532, COSV62384765; called by muse, mutect2
- SAMD9 | c.2646T>G p.F882L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1181483736, COSV66074587; called by muse, mutect2, varscan2
- SATB2 | c.1900C>A p.H634N | Missense Mutation (SNP) | VAF 158/510 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV53488830; called by muse, mutect2, varscan2
- SCAPER | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV57738869; called by muse, mutect2, varscan2
- SCN3A | c.5470C>T p.L1824F | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51809538; called by muse, mutect2, varscan2
- SCN8A | c.5596C>T p.R1866W | Missense Mutation (SNP) | VAF 220/584 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61978562; called by muse, mutect2, varscan2
- SCN9A | c.5573C>A p.S1858Y (on ENST00000303354; = p.S1847Y on NM_002977.3) | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); catalogued as COSV104409004, COSV57624075; called by muse, mutect2, varscan2
- SCN9A | c.5474C>T p.A1825V (on ENST00000303354; = p.A1814V on NM_002977.3) | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs759259640; called by muse, mutect2, varscan2
- SCN9A | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 83/225 reads (37%) | catalogued as rs1448265143, COSV100313383; called by muse, mutect2, varscan2
- SDAD1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs548168022, COSV62403183; called by muse, mutect2, varscan2
- SEC24B | c.2823C>A p.F941L | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as COSV54498800; called by muse, mutect2, varscan2
- SEC31A | c.1171C>T p.R391* | Nonsense Mutation (SNP) | VAF 58/130 reads (45%) | catalogued as rs752371637, COSV52342403; called by muse, mutect2, varscan2
- SELENBP1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770573479, COSV100923671; called by muse, mutect2, varscan2
- SEMA3E | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as rs865986651, COSV57081317; called by muse, mutect2, varscan2
- SEMA6D | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 76/222 reads (34%) | catalogued as rs1265629390; called by muse, varscan2
- SEMA6D | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760143548; called by muse, mutect2, varscan2
- SEZ6L | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.805); catalogued as rs148526431, COSV99962711; called by muse, mutect2, varscan2
- SFRP4 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as rs140561432, COSV71412308; called by muse, mutect2, varscan2
- SGCZ | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66013720; called by muse, mutect2, varscan2
- SHROOM4 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782490910; called by muse, mutect2, varscan2
- SI | c.5212G>T p.D1738Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs774160456, COSV52274978; called by muse, mutect2, varscan2
- SIGLEC10 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as rs868611106; called by muse, mutect2, varscan2
- SIGLEC8 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.943); catalogued as COSV58474144, COSV58475788; called by muse, mutect2, varscan2
- SIK2 | c.479-1G>A p.X160_splice | Splice Site (SNP) | VAF 44/102 reads (43%) | catalogued as COSV59250362; called by muse, mutect2, varscan2
- SKOR1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs754475080; called by muse, mutect2, varscan2
- SLC12A1 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100372686; called by muse, mutect2, varscan2
- SLC16A6 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as COSV100517200; called by muse, mutect2, varscan2
- SLC17A3 | c.44A>C p.K15T | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as COSV57761647; called by muse, mutect2, varscan2
- SLC24A1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99978502; called by muse, mutect2, varscan2
- SLC28A3 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201060612, COSV66153207; called by muse, mutect2, varscan2
- SLC46A3 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs749247276; called by muse, mutect2, varscan2
- SLC47A1 | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs770635889; called by muse, mutect2, varscan2
- SLC9A7 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201653332, COSV60377306; called by muse, mutect2, varscan2
- SMAD1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs750014334, COSV57472527; called by muse, mutect2, varscan2
- SMARCA1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64412867, COSV64413061; called by muse, mutect2, varscan2
- SMARCA2 | c.4261C>T p.R1421* | Nonsense Mutation (SNP) | VAF 52/216 reads (24%) | catalogued as COSV56645532; called by muse, mutect2, varscan2
- SMARCD2 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs750388563, COSV56741112; called by muse, mutect2, varscan2
- SMG6 | c.1210C>A p.R404S | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99558336; called by muse, mutect2, varscan2
- SMG7 | c.2438T>G p.I813S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV100750572; called by muse, mutect2, varscan2
- SMURF1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.979); catalogued as COSV63156381; called by muse, mutect2, varscan2
- SMYD3 | c.638C>T p.S213L (on ENST00000490107 / NM_001375962.1; = p.S154L on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs758081490, COSV63625860; called by muse, mutect2, varscan2
- SNX32 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs766218846; called by muse, mutect2, varscan2
- SPATA13 | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1439323626; called by muse, mutect2, varscan2
- SPATA4 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs770387558; called by muse, mutect2, varscan2
- SPDL1 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1432894848; called by muse, mutect2, varscan2
- SPEN | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777234386, COSV65366041; called by muse, mutect2, varscan2
- SPON1 | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 92/301 reads (31%) | catalogued as COSV59957477; called by muse, mutect2, varscan2
- SPRTN | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.246); catalogued as COSV50477592; called by muse, mutect2, varscan2
- SPTB | c.4127C>T p.S1376L | Missense Mutation (SNP) | VAF 139/396 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs200559187; called by muse, mutect2, varscan2
- SPTBN4 | c.6919G>A p.E2307K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV58944094; called by muse, mutect2, varscan2
- SPTLC1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs143232538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRRM4 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 42/130 reads (32%) | catalogued as COSV57408995; called by muse, mutect2, varscan2
- SRRM4 | c.516-1G>T p.X172_splice | Splice Site (SNP) | VAF 26/74 reads (35%) | catalogued as COSV57416569; called by muse, mutect2, varscan2
- STAC2 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs1301027550; called by muse, mutect2, varscan2
- STARD9 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1259002857, COSV51904268; called by muse, mutect2, varscan2
- STIL | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 115/343 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147160336, COSV54548935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK3 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs750630819, COSV69222340; called by muse, mutect2, varscan2
- STX18 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs375534518, COSV104402321; called by muse, mutect2, varscan2
- STX2 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs928644533, COSV55435844; called by muse, mutect2, varscan2
- STXBP3 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as rs543363224, COSV100893990; called by muse, mutect2, varscan2
- SUCO | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs199510939, COSV55264924; called by muse, mutect2, varscan2
- SULF1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs762343638, COSV52676968; called by muse, mutect2
- SUN5 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs746468014, COSV62181084, COSV62181720; called by muse, mutect2, varscan2
- SUPT7L | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58134159; called by muse, mutect2, varscan2
- SV2A | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs782100472, COSV64964217; called by muse, mutect2, varscan2
- SVIL | c.3937C>T p.R1313C (on ENST00000355867 / NM_021738.3; = p.R887C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs141855067; called by muse, mutect2, varscan2
- SYDE2 | c.932G>T p.R311I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs149293965, COSV52317793; called by muse, mutect2, varscan2
- SYN2 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774872501, COSV70285203; called by muse, mutect2, varscan2
- SYNE1 | c.3004C>T p.R1002* (on ENST00000367255 / NM_182961.4; = p.R1009* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 73/180 reads (41%) | catalogued as rs1264723962, COSV55086157; called by muse, mutect2, varscan2
- SYTL5 | c.1602G>T p.E534D | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1569194277, COSV99937448; called by muse, varscan2
- TAF1L | c.2772G>T p.E924D | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV54264708; called by muse, mutect2, varscan2
- TAPBPL | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs758936057, COSV56946763; called by muse, mutect2
- TARS1 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV99465434, COSV99466160; called by muse, mutect2, varscan2
- TAS2R14 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs375585680; called by muse, mutect2, varscan2
- TAS2R16 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs779112612, COSV50797336; called by muse, mutect2, varscan2
- TBC1D22A | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.492); catalogued as rs759769107, COSV61437613; called by muse, mutect2, varscan2
- TBCK | c.2186C>T p.S729L (on ENST00000273980 / NM_001163436.4; = p.S666L on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs766412998, COSV56755756; called by muse, mutect2, varscan2
- TBL1XR1 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV70501035, COSV99081487; called by muse, mutect2, varscan2
- TCEA1 | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.649); catalogued as COSV67172293; called by muse, mutect2, varscan2
- TDO2 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs775054654; called by muse, mutect2, varscan2
- TEAD4 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.963); catalogued as rs1172254434; called by muse, mutect2, varscan2
- TECTA | c.4288G>A p.D1430N | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs906326110, COSV50720111; called by muse, mutect2, varscan2
- TESC | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs756764036, COSV100069366; called by muse, mutect2, varscan2
- TEX10 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs757589553, COSV66516263; called by muse, mutect2, varscan2
- TEX13A | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs782414664, COSV61178019; called by muse, mutect2, varscan2
- TEX14 | c.2965C>T p.R989* (on ENST00000240361 / NM_001201457.2; = p.R983* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 90/262 reads (34%) | catalogued as rs1042684265; called by muse, mutect2, varscan2
- TEX15 | c.89C>A p.S30Y (on ENST00000256246; = p.S413Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV56346365, COSV56349511; called by muse, mutect2, varscan2
- TEX51 | c.202C>T p.R68C (on ENST00000643416; = p.R50C on NM_001322244.2) | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as rs532751361; called by muse, mutect2, varscan2
- TFB1M | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 169/486 reads (35%) | catalogued as COSV100905243; called by muse, mutect2, varscan2
- TFDP1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64743118; called by muse, mutect2, varscan2
- TGOLN2 | c.1349G>T p.R450I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs370369759; called by muse, varscan2
- THAP7 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1184685680; called by muse, mutect2, varscan2
- THEMIS | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.293); catalogued as COSV64069889; called by muse, mutect2, varscan2
- THNSL1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1367567712, COSV64479123; called by muse, mutect2, varscan2
- TINAG | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as rs1554202233, COSV52516279; called by muse, mutect2, varscan2
- TINAGL1 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs375984520; called by muse, mutect2, varscan2
- TJP3 | c.1879G>A p.V627M | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs955970013, COSV53664453; called by muse, mutect2, varscan2
- TLE1 | c.1331+1G>A p.X444_splice | Splice Site (SNP) | VAF 58/153 reads (38%) | catalogued as COSV64690173; called by muse, varscan2
- TLL1 | c.2919G>T p.E973D | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.325); catalogued as COSV50265253, COSV50285293; called by muse, mutect2, varscan2
- TLN2 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.565); catalogued as rs779049063, COSV60894489; called by muse, mutect2, varscan2
- TMC3 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371581223; called by muse, mutect2, varscan2
- TMC5 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV66864300; called by muse, mutect2, varscan2
- TMEM196 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.953); catalogued as COSV101337479; called by muse, mutect2, varscan2
- TMEM214 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs185429302; called by muse, mutect2, varscan2
- TMEM97 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as rs782366453; called by muse, mutect2, varscan2
- TMPRSS11F | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs377605520; called by muse, mutect2, varscan2
- TMTC3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376704540, COSV57124321; called by muse, varscan2
- TNRC6B | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57292351; called by muse, mutect2, varscan2
- TOM1L2 | c.796C>T p.R266W (on ENST00000379504 / NM_001350333.2; = p.R216W on NM_001033551.3) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775756759; called by muse, mutect2, varscan2
- TPP1 | c.53A>C p.K18T | Missense Mutation (SNP) | VAF 136/355 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.01); catalogued as COSV54998319; called by muse, mutect2, varscan2
- TPTE | c.1222C>T p.L408F (on ENST00000618007 / NM_199261.4; = p.L390F on NM_199259.4) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs267606169; called by muse, mutect2, varscan2
- TRAF3IP3 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs12732140, COSV50554030; called by muse, mutect2, varscan2
- TREX2 | c.709G>A p.V237M (on ENST00000334497; = p.V194M on NM_080701.3) | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556979239; called by muse, mutect2, varscan2
- TRIP4 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 125/373 reads (34%) | catalogued as rs368346982; called by muse, mutect2, varscan2
- TRNT1 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99285666; called by muse, mutect2
- TRPC1 | c.1534C>T p.R512C (on ENST00000476941 / NM_001251845.2; = p.R478C on NM_003304.4) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs929868284, COSV56427512; called by muse, mutect2, varscan2
- TRPC3 | c.655G>A p.D219N (on ENST00000379645 / NM_001366479.2; = p.D146N on NM_003305.2) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs868073711, COSV53371571; called by muse, mutect2, varscan2
- TRPM8 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 173/481 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs201939575, COSV61221390; called by muse, mutect2, varscan2
- TSC22D1 | c.1022G>A p.S341N | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs780757240; called by muse, mutect2, varscan2
- TTC30B | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs771411917, COSV68809809; called by muse, mutect2, varscan2
- TTC37 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs368404161; called by muse, varscan2
- TTF2 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101037485; called by muse, mutect2, varscan2
- TTLL7 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53083843; called by muse, mutect2, varscan2
- TTLL9 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs776756851; called by muse, mutect2, varscan2
- TTN | c.87350G>T p.R29117I (on ENST00000591111; = p.R21693I on NM_003319.4) | Missense Mutation (SNP) | VAF 42/147 reads (29%) | PolyPhen probably damaging (0.997); catalogued as COSV59906286, COSV60194742; called by muse, mutect2, varscan2
- TTN | c.70087C>T p.R23363C (on ENST00000591111; = p.R15939C on NM_003319.4) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | PolyPhen possibly damaging (0.727); catalogued as rs1320326326, COSV59934151; called by muse, mutect2, varscan2
- TTN | c.42799C>T p.R14267C (on ENST00000591111; = p.R6843C on NM_003319.4) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | PolyPhen probably damaging (0.998); catalogued as rs767724702, COSV100587926, COSV59902174; called by muse, mutect2
- TTN | c.40373A>G p.N13458S (on ENST00000591111; = p.N6034S on NM_003319.4) | Missense Mutation (SNP) | VAF 118/344 reads (34%) | PolyPhen benign (0); catalogued as rs1239591907; called by muse, mutect2, varscan2
- TTN | c.14456C>T p.S4819L (on ENST00000591111; = p.S3892L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | PolyPhen possibly damaging (0.452); catalogued as rs764310312, COSV59969202; called by muse, mutect2, varscan2
- TTN | c.12289C>A p.L4097I (on ENST00000591111; = p.L4051I on NM_003319.4) | Missense Mutation (SNP) | VAF 83/259 reads (32%) | catalogued as COSV59922373; called by muse, mutect2, varscan2
- TTN | c.9442C>T p.R3148C (on ENST00000591111; = p.R3102C on NM_003319.4) | Missense Mutation (SNP) | VAF 58/218 reads (27%) | PolyPhen probably damaging (0.998); catalogued as rs372196051, COSV59954093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.7951G>A p.E2651K (on ENST00000591111; = p.E2605K on NM_003319.4) | Missense Mutation (SNP) | VAF 83/206 reads (40%) | PolyPhen benign (0.003); catalogued as rs770388400; called by muse, mutect2, varscan2
- TTN | c.3035G>A p.R1012Q (on ENST00000591111; = p.R966Q on NM_003319.4) | Missense Mutation (SNP) | VAF 81/227 reads (36%) | PolyPhen possibly damaging (0.67); catalogued as rs368885310, COSV59900472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.1316C>A p.S439Y | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV68029782; called by muse, mutect2, varscan2
- TUBE1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267600765; called by muse, mutect2, varscan2
1,290 further variants in this file (652 protein-altering or splice-affecting, 390 silent, 248 other) are not listed here.
